CCDI case PBBRVL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e973f0c5-0d95-4cc2-9ed5-8b8893ca049d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 5.2 years (1,896 days).

Biospecimens (3 samples)
- Sample 0DF85F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF86I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DF86J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
